Gene-level copy-number profile of tumor specimen MP2PRT-PATHSK-TBP1-A from MP2PRT case MP2PRT-PATHSK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (817 days).
Specimen MP2PRT-PATHSK-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 02b39a35-18f4-4383-bfa1-c3d4df91ddfa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATHSK-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/3cc79433-b6e1-48fe-82f0-59f17785a783

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 117; copy number 1: 3,077; copy number 2: 55,058; copy number 3: 261; copy number 5: 255; copy number 6: 31; copy number 7: 19; copy number 8: 82; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): 117 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,252,211–89,254,015, 2 genes: IGKV3-31, IGKV1-32.
- chr14:22,415,362–22,516,331, 46 genes (within-gene range 0–1): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29, TRAJ28, TRAJ27.
- chr14:105,851,705–106,264,715, 69 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 391 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:20,256,752–25,057,746, 45 genes, copy number 5–7 (within-gene range 3–7): LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692.
- chr21:24,938,431–25,361,868, 8 genes, copy number 5 (within-gene range 3–5): AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489.
- chr21:25,561,909–25,607,517, 4 genes, copy number 5: MIR155HG, MIR155, AP000223.1, MRPL39.
- chr21:26,158,091–26,217,381, 3 genes, copy number 5 (within-gene range 3–5): AP001439.1, AP000229.1, RNU6-926P.
- chr21:32,259,804–32,393,012, 6 genes, copy number 5 (within-gene range 3–5): AP000265.1, MIS18A, MIS18A-AS1, MRAP, MRAP-AS1, URB1.
- chr21:33,229,901–34,360,033, 29 genes, copy number 5–7: IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON, AP000311.1, CRYZL1, ITSN1, ATP5PO, LINC00649, RN7SL740P, AP000569.1, MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1.
- chr21:34,787,801–44,801,826, 261 genes, copy number 5–8 (broad region; genes not listed).
- chr21:45,336,707–45,404,369, 5 genes, copy number 5: BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1.
- chr21:45,974,489–46,691,226, 30 genes, copy number 5–9: AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
